Surgical pathology report (de-identified scan), TCGA case TCGA-3A-A9IC, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Moffitt Cancer Center, specimen TCGA-3A-A9IC-01A (Primary Tumor).

[page 1 of 3]
Pathology Report

ICD O-3
Adenocarcinoma, duct NOS
8500/3
Site: Pancreas head
C25.0
Q4 4/16/14

Final Diagnosis

- A. BILE DUCT, PANCREAS, DUODENUM, WHIPPLE PROCEDURE:
Invasive pancreatic ductal adenocarcinoma, moderately differentiated.
See Key Pathological Findings.
- B. ADDITIONAL PANCREATIC MARGIN, EXCISION:
Pancreatic intraepithelial neoplasia low grade.
There is no evidence of carcinoma and/or high grade dysplasia.

I, . the attending pathologist, personally reviewed all
slides and / or materials and rendered the final diagnosis. Electronically
Signed Out by

Key Pathological Findings

A: Pancreas-Exocrine Synoptic Data

SPECIMEN TYPE: Pancreaticoduodenectomy (Whipple resection), partial pancreatectomy

TUMOR SITE:

Pancreatic head

TUMOR SIZE: Invasive:

4 x 3.5 x 2.5 cm

***OTHER ORGANS RESECTED::**

*Duodenum

Ductal adenocarcinoma

HISTOLOGIC GRADE: G2: Moderately differentiated

EXTENT OF INVASION - PRIMARY TUMOR: Tumor invades adjacent structures/organs

Duodenum

PRIMARY TUMOR (pT): pT3: Tumor extends beyond the pancreas but without involvement of the
celiac axis or the superior mesenteric artery

REGIONAL LYMPH NODES (pN): pN1b: Metastasis in multiple regional lymph nodes

Number examined: 21

Number involved: 4

DISTANT METASTASIS (pM): pMX: Cannot be assessed

MARGINS:

Margins free of tumor

Distance of invasive carcinoma from closest margin: 1 mm

*Specify margin (if possible): retroperitoneal margin

PANCREATIC RESECTION MARGIN, INVOLVED BY::

PanIN1b

*VENOUS (LARGE VESSEL) INVASION (V): *Absent

*LYMPHATIC (SMALL VESSEL) INVASION (L): *Present

[page 2 of 3]
*PERINEURAL INVASION: *Present
*ADDITIONAL PATHOLOGIC FINDINGS:
*Acute pancreatitis
*Chronic pancreatitis

Specimen(s) Received

A BILE DUCT, PANCREAS, DUODENUM FS
B ADDITIONAL PANCREATIC MARGIN FS

Clinical History

Not given.

Preoperative Diagnosis

Pancreatic adenocarcinoma.

Intraoperative Consultation

FSA BILE DUCT, PANCREAS, DUODENUM:
Common bile duct margin free of invasive carcinoma, focal intraductal papillary mucinous neoplasia (IPMN) present (obscuring cavity artifact present).

Intradepartmental Consultation: The case was also reviewed by MD, who concurs with the above interpretation.

FSB ADDITIONAL PANCREATIC MARGIN:
No evidence of malignancy.

Comment: This frozen section diagnosis/result was communicated to and acknowledged by Dr. in frozen section room at

MD and MD, have performed the intraoperative consultations and issued the above diagnosis.

Gross Description

A. The specimen is received fresh for frozen section analysis labeled "bile duct, pancreas, duodenum." The specimen consists of a resected portion of the pancreatic head (4.5 x 4 x 3 cm) and attached duodenum (12 cm in length and 6 cm in greatest circumference). The serosal surface of the duodenum is brown-tan and smooth. Upon opening, the lumen contains a moderate amount of viscous bile. The mucosal surface of the duodenum exhibits normal folds with no gross evidence of polyps or nodularity.

The pancreatic margin resection is marked with black ink, the portal vein groove is marked with blue ink and the retroperitoneal surface is marked with green ink. There is no stapled line grossly present that would indicate the superior mesentery artery. A palpable pancreatic mass is identified. The pancreatic duct is not probe patent and is totally occluded by the presence of the tumor. Serial sectioning into the pancreas reveals a firm, yellow-gray, ill-defined mass (4 x 3.5 x 2.5 cm), which abuts the retroperitoneal surface/uncinate process. Grossly the mass does

[page 3 of 3]
appear to involve the common bile duct, which is probe patent and somewhat dilated with an inserted catheter. Grossly the mass does appear to involve the duodenal wall extending to the mucosal surface and grossly involving the ampulla of Vater. There is a minimal amount of grossly uninvolved pancreatic tissue. A section of the minimal amount of attached adipose tissue isolates 2 moderately firm, round, tan, irregular lymph nodes, which measure 1.5 cm in greatest dimension. The lymph nodes are isolated adjacent to the pancreas. A representative frozen section is taken and submitted as FSA1. Permanent sections are submitted as:

- A2: Mirror image of tumor submitted to Tissue Bank.
- A3: Tangential pancreatic margin attached to specimen.
- A4: Perpendicular portal vein groove.
- A5: Tangential proximal duodenal margin of resection.
- A6: Tangential distal duodenal margin of resection.
- A7-A8: Sections of tumor showing relationship to retroperitoneal surface (green ink).
- A9-A10: Tumor showing its relationship to common bile duct and ampulla of Vater.
- A11: Tumor showing its relationship to duodenum.
- A12: Grossly unremarkable pancreas.
- A13: Grossly unremarkable duodenal mucosa.
- A14: One bisected lymph node.
- A15: One bisected lymph node.
- A16-A18: Entire remaining adipose tissue.

A representative section of the tumor is submitted to the Tissue Procurement Laboratory.

B. The specimen is received fresh for frozen section analysis labeled "additional pancreatic margin." The specimen consists of a 3 x 1.5 x 0.5 cm, firm, gray-yellow, irregular fragment of tissue. The margin is entirely submitted tangentially for frozen section as FSB1.

Source: NCI Genomic Data Commons file 6c7310a2-8825-4253-8619-0b01c24ef604 (TCGA-3A-A9IC.74597CF2-71A6-4F3A-91E5-F22FD31D4417.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).